Gene-level copy-number profile of tumor specimen TCGA-KL-8336-01A from TCGA case TCGA-KL-8336, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 51.5 years (18,821 days).
Specimen TCGA-KL-8336-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KICH.0902d8cf-f32c-48c5-9183-acd96cdac552.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KL-8336-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ddc44595-bbc9-4c67-8340-fc4e65da7cce

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 29,591; copy number 2: 30,198.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KL-8336-01A-11D-2308-01): tumor purity 0.85, ploidy 1.54, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:75,455,994–76,595,678, 23 genes: GAPDHP57, EVA1A, AC007099.2, AC007099.3, AC007099.1, AC005034.1, U3, MRPL19, SUPT4H1P1, GCFC2, AC005034.3, AC005034.5, AC005034.2, AC005034.6, AC005034.4, AC110614.1, SUCLA2P2, AC073091.1, AC073091.2, PNPP1, USP21P2, RN7SKP203, RN7SKP164.
- chr6:158,232,236–158,635,428, 8 genes (within-gene range 0–1): TULP4, SRP72P2, AL360169.2, AL360169.3, AL360169.1, RN7SL173P, CACYBPP3, TMEM181.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 27,170. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
